Gene-level copy-number profile of tumor specimen TCGA-77-8154-01A from TCGA case TCGA-77-8154, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.5 years (24,640 days).
Specimen TCGA-77-8154-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.0f301782-1b61-47d0-8fdb-b3e3a184276d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-77-8154-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ed8d252a-aebb-4a42-9b14-0f7bb43d5579

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 17,439; copy number 2: 34,681; copy number 3: 6,302; copy number 4: 881; copy number 5: 305; copy number 6: 87; copy number 7: 44; copy number 9: 46; copy number 16: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-77-8154-01A-11D-2243-01): tumor purity 0.68, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr21:41,141,493–42,297,244, 31 genes (within-gene range 0–1): LINC00323, MIR3197, BACE2, PLAC4, BACE2-IT1, FAM3B, MX2, MX1, AP001610.2, TMPRSS2, AP001610.1, AP001610.3, AP006748.1, PCSEAT, LINC00111, LINC00479, LINC00112, RIPK4, AP001615.1, MIR6814, PRDM15, AP001619.2, AP001619.1, AP001619.3, C2CD2, ZBTB21, ZNF295-AS1, UMODL1, UMODL1-AS1, ABCG1, RNA5SP492.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 485 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:197,902,630–198,322,420, 4 genes, copy number 5 (within-gene range 3–5): C1orf53, LHX9, NEK7, PRR13P1.
- chr8:33,604,856–34,039,104, 1 gene, copy number 6 (within-gene range 1–6): AF279873.3.
- chr8:33,859,480–38,704,855, 86 genes, copy number 6 (broad region; genes not listed).
- chr8:42,391,624–43,674,591, 44 genes, copy number 7: VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr11:30,384,493–30,586,872, 1 gene, copy number 5 (within-gene range 1–5): MPPED2.
- chr11:30,584,130–32,104,665, 17 genes, copy number 5 (within-gene range 3–5): MPPED2-AS1, AL122014.1, DCDC1, CYCSP25, AL137804.1, DNAJC24, IMMP1L, ELP4, AC131571.1, PAX6, PAUPAR, AL035078.4, AL035078.1, AL035078.3, AL035078.2, U3, EIF4A2P5.
- chr16:23,463,542–26,607,396, 62 genes, copy number 5–16 (within-gene range 1–16) (broad region; genes not listed).
- chr16:27,998,295–31,528,803, 270 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,024. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
